Somatic mutation profile of tumor specimen MP2PRT-PAPYRA-TMP1-A (aliquot MP2PRT-PAPYRA-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPYRA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,088 days).
Specimen MP2PRT-PAPYRA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f4226f6-811b-4c67-8fb6-7997bf01712f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPYRA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPYRA-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0b2bd3e-b0cb-4712-a0fd-4ae6bea87c04

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRX | c.4121T>G p.V1374G | Missense Mutation (SNP) | VAF 275/639 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs773512610; ClinVar: uncertain significance; called by muse, varscan2
- RABEP1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1397428755, COSV52582598; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- AATK | c.1855C>A p.L619M (on ENST00000326724 / NM_001080395.3; = p.L516M on NM_004920.2) | Missense Mutation (SNP) | VAF 282/645 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- BEND4 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DOCK4 | c.5531C>T p.S1844L | Missense Mutation (SNP) | VAF 198/476 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IARS2 | c.2871A>T p.K957N | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFPL4A | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- UBE2D3 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
